Somatic mutation profile of tumor specimen TCGA-2Z-A9J7-01A (aliquot TCGA-2Z-A9J7-01A-11D-A382-10) from TCGA case TCGA-2Z-A9J7, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.6 years (23,230 days).
Specimen TCGA-2Z-A9J7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 271a1da3-4499-41c2-a019-f9538d978bb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9J7-10A (Blood Derived Normal), aliquot TCGA-2Z-A9J7-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7618e6c1-d576-444b-9c61-9139844ac3ef

The open-access MAF lists 45 somatic variants for this specimen: 29 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 24, Silent 16, Nonsense Mutation 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH11 | c.6727C>T p.R2243* | Nonsense Mutation (SNP) | VAF 16/263 reads (6%) | catalogued as rs201943194; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ATP5MC1 | c.329A>C p.Y110S | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs763495185, COSV100582445, COSV100582452; called by muse, mutect2, varscan2
- BRCA2 | c.2447A>G p.E816G | Missense Mutation (SNP) | VAF 139/292 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as rs1555282673, COSV101204711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDC42BPA | c.2363C>G p.T788S | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100507138; called by muse, mutect2, varscan2
- CDH13 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs374048975, COSV99232325; called by muse, mutect2, varscan2
- CLTC | c.1643A>G p.Q548R | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.968); catalogued as COSV99293055; called by muse, mutect2, varscan2
- CUL1 | c.1466T>G p.I489S | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100296985; called by muse, mutect2, varscan2
- E2F7 | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV100524075; called by muse, mutect2
- EGR4 | c.794C>G p.S265W (on ENST00000545030; = p.S162W on NM_001965.4) | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV101474283, COSV71532004; called by muse, mutect2, varscan2
- FUBP1 | c.337G>T p.G113* | Nonsense Mutation (SNP) | VAF 74/161 reads (46%) | catalogued as COSV99629776; called by muse, mutect2, varscan2
- GRM3 | c.2314G>A p.G772S | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV64471706; called by muse, mutect2, varscan2
- JAKMIP2 | c.839A>T p.D280V | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99509470; called by muse, mutect2, varscan2
- KATNAL2 | c.1390T>C p.S464P (on ENST00000356157 / NM_001353899.1; = p.S392P on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99798499; called by muse, mutect2, varscan2
- KIF1B | c.1103T>A p.L368Q (on ENST00000377086 / NM_001365952.1; = p.L362Q on NM_015074.3) | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99824425; called by muse, mutect2, varscan2
- KLHL7 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.651); catalogued as COSV100178528; called by muse, mutect2, varscan2
- LCTL | c.316A>T p.N106Y | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV100427335; called by muse, mutect2, varscan2
- PCDHGC4 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.804); catalogued as COSV99342892; called by muse, mutect2, varscan2
- PEX6 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as rs1554128505, COSV99769658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCXD1 | c.142A>C p.M48L | Missense Mutation (SNP) | VAF 149/160 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV101088027; called by muse, mutect2, varscan2
- PLK3 | c.215del p.X72_splice | Splice Site (DEL) | VAF 29/70 reads (41%) | catalogued as rs767753648; called by mutect2, pindel, varscan2
- PTGER3 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.282); catalogued as rs767646488, COSV100139874; called by muse, mutect2, varscan2
- PTPRD | c.2508G>A p.M836I | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as rs724159858, COSV61925286, COSV61975357; called by muse, mutect2, varscan2
- RYR2 | c.11176T>C p.Y3726H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100773307; called by muse, mutect2, varscan2
- S100PBP | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.856); catalogued as COSV100758408; called by muse, mutect2, varscan2
- UQCR10 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 34/71 reads (48%) | catalogued as rs377432442, COSV57458710; called by muse, mutect2, varscan2
- USP36 | c.1676C>T p.S559L | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs532327037, COSV100361933; called by muse, mutect2, varscan2
- ZNF180 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.45); catalogued as COSV55419638, COSV55421868; called by muse, mutect2, varscan2
- ZNF622 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100433201; called by muse, mutect2, varscan2
- CFDP1 | c.810-11_819del p.X270_splice | Splice Site (DEL) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- ACSF3 | c.546G>T p.P182= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as COSV100441666; called by muse, mutect2, varscan2
- ADD3 | c.1398C>T p.I466= | Silent (SNP) | VAF 92/183 reads (50%) | catalogued as COSV99523819; called by muse, mutect2, varscan2
- C9orf72 | c.1263G>A p.Q421= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs812272, COSV101187067; called by muse, mutect2, varscan2
- CACNA1B | c.2136G>C p.L712= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as COSV99500514; called by muse, mutect2, varscan2
- CDC20 | c.591A>G p.V197= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as COSV100196714; called by muse, mutect2, varscan2
- CMYA5 | c.9051A>G p.K3017= | Silent (SNP) | VAF 182/382 reads (48%) | catalogued as COSV101484453; called by muse, mutect2, varscan2
- CUBN | c.6543A>G p.S2181= | Silent (SNP) | VAF 159/336 reads (47%) | catalogued as COSV100913731; called by muse, mutect2, varscan2
- ITGB8 | c.189A>G p.P63= | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as rs769150608, COSV99752641; called by muse, mutect2, varscan2
- MFAP1 | c.582G>A p.E194= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs768360268, COSV99980202; called by muse, mutect2, varscan2
- NUP133 | c.2082C>A p.S694= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV99773635; called by muse, mutect2
- OPLAH | c.1005C>T p.A335= | Silent (SNP) | VAF 78/162 reads (48%) | catalogued as rs1554759826, COSV101470992; called by muse, mutect2, varscan2
- PLPP1 | c.198C>T p.F66= | Silent (SNP) | VAF 48/109 reads (44%) | catalogued as COSV99302142; called by muse, mutect2, varscan2
- SAA2-SAA4 | c.351T>C p.Y117= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as COSV53447895; called by muse, mutect2, varscan2
- SOX9 | c.705G>A p.P235= | Silent (SNP) | VAF 81/292 reads (28%) | catalogued as COSV55424261; called by muse, mutect2, varscan2
- TRAPPC12 | c.786C>G p.P262= | Silent (SNP) | VAF 47/109 reads (43%) | catalogued as COSV100160373, COSV100161072; called by muse, mutect2, varscan2
- TSPYL5 | c.798G>A p.L266= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV100439181; called by muse, mutect2, varscan2
